Somatic mutation profile of tumor specimen TCGA-HT-8114-01A (aliquot TCGA-HT-8114-01A-11D-2395-08) from TCGA case TCGA-HT-8114, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.1 years (13,198 days).
Specimen TCGA-HT-8114-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc1a89cd-3cf5-4414-86e5-855f91e06bbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8114-10A (Blood Derived Normal), aliquot TCGA-HT-8114-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cdb0ca5-360f-4fe2-8483-698dde61111d

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/95 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.560-2A>G p.X187_splice | Splice Site (SNP) | VAF 29/44 reads (66%) | hotspot (GDC flag); catalogued as rs1427441061, CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.14294C>T p.A4765V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV101315601; called by muse, mutect2
- FAT2 | c.4025C>T p.P1342L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs766913068, COSV55819903, COSV55823153; called by muse, mutect2, varscan2
- HDX | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as COSV52978637; called by muse, mutect2, varscan2
- PCDH12 | c.3342C>G p.S1114R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV51522391; called by muse, mutect2, varscan2
- PKLR | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as rs1557960823; called by muse, mutect2
- ROM1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs748080594, COSV53882210; called by muse, mutect2, varscan2
- SRPRA | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1345189937, COSV55007538; called by muse, mutect2, varscan2
- SULT6B1 | c.903C>G p.C301W (on ENST00000535679 / NM_001367551.1; = p.C263W on NM_001032377.2) | Missense Mutation (SNP) | VAF 5/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53194657; called by muse, mutect2
- ZC3H14 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1472647006, COSV51771079; called by muse, mutect2, varscan2
- ZNF235 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs773680891, COSV52157229; called by muse, mutect2
- ATRX | c.3145dup p.I1049Nfs*4 | Frame Shift Ins (INS) | VAF 34/72 reads (47%) | called by mutect2, varscan2
- ATRX | c.2656_2659del p.E886Lfs*18 | Frame Shift Del (DEL) | VAF 25/214 reads (12%) | called by mutect2, varscan2
- MASTL | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 5/129 reads (4%) | called by muse, mutect2
- TTN | c.33817G>C p.V11273L (on ENST00000591111; = p.V10346L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | PolyPhen benign (0); called by muse, mutect2
- C1D | c.411A>C p.G137= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV63413550; called by muse, mutect2, varscan2
- GAS6 | c.1164G>A p.A388= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs375788560; called by muse, mutect2, varscan2
- ITSN1 | c.2535G>A p.T845= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs763031843, COSV66083045; called by muse, mutect2
- MAP7 | c.1641G>A p.Q547= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV63420989; called by muse, mutect2, varscan2
